Somatic mutation profile of tumor specimen TCGA-DE-A4MD-01A (aliquot TCGA-DE-A4MD-01A-11D-A257-08) from TCGA case TCGA-DE-A4MD, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 71.7 years (26,179 days).
Specimen TCGA-DE-A4MD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6247277-76ed-4d27-9818-b025ffc80fa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DE-A4MD-10A (Blood Derived Normal), aliquot TCGA-DE-A4MD-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87994094-6769-4094-a8ff-7ea10279321f

The open-access MAF lists 31 somatic variants for this specimen: 20 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 17, Silent 11, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MEN1 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 13/13 reads (100%) | catalogued as rs1565648511, CM983963, COSV53640162; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANGPT2 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as rs760458544, COSV57337388; called by muse, mutect2, varscan2
- BSN | c.2768C>G p.T923S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99608929; called by muse, mutect2, varscan2
- CLDN14 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748110915, COSV100578830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOLH1 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.625); catalogued as rs1320150009, COSV57051866; called by muse, mutect2, varscan2
- FRY | c.5387T>C p.I1796T | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs771829292, COSV100969454; called by muse, mutect2, varscan2
- GBF1 | c.3926A>T p.N1309I (on ENST00000369983 / NM_001377137.1; = p.N1308I on NM_004193.3) | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV100890548; called by muse, mutect2, varscan2
- KCNJ9 | c.233T>A p.I78N | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100927766; called by muse, mutect2, varscan2
- LRPPRC | c.2936A>G p.N979S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV99580920; called by muse, mutect2, varscan2
- LRRK2 | c.6422C>T p.T2141M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111691891, CM081687, COSV54149375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR12D3 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV101011343; called by muse, mutect2, varscan2
- PCNX2 | c.3406G>A p.V1136M | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs370457665; called by muse, mutect2, varscan2
- PEX5 | c.1843G>T p.G615C (on ENST00000420616; = p.G607C on NM_000319.5) | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99871063; called by muse, mutect2, varscan2
- RPS4X | c.647A>T p.N216I | Missense Mutation (SNP) | VAF 43/43 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV100289092; called by muse, mutect2, varscan2
- RYR2 | c.3641G>A p.R1214K | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as rs775350665, COSV100771402; called by muse, mutect2, varscan2
- STAT5A | c.483G>T p.E161D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs147867237; called by muse, varscan2
- TACR3 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100510623; called by muse, mutect2, varscan2
- TCTN2 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 33/61 reads (54%) | catalogued as rs1189889973, COSV100315273; called by muse, mutect2, varscan2
- TG | c.4544_4546del p.Q1515del | In Frame Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- CTTNBP2 | c.1836A>C p.P612= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV99354249; called by muse, mutect2, varscan2
- DDN | c.312G>A p.E104= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100305256; called by muse, mutect2, varscan2
- HUS1B | c.171G>A p.E57= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV100033808; called by muse, mutect2, varscan2
- IRF2BP1 | c.1665C>T p.V555= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs1228539719, COSV100138813; called by muse, mutect2, varscan2
- KMT2B | c.3549C>T p.N1183= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs1050840595, COSV55865430; called by muse, mutect2, varscan2
- MOK | c.396A>G p.E132= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99513308; called by muse, mutect2, varscan2
- NYNRIN | c.5313C>T p.P1771= | Silent (SNP) | VAF 48/87 reads (55%) | catalogued as COSV101230631; called by muse, mutect2, varscan2
- ST18 | c.2319C>T p.C773= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs369209561; called by muse, mutect2, varscan2
- STAT5A | c.484C>T p.L162= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100604652; called by muse, mutect2, varscan2
- USP53 | c.303T>C p.A101= | Silent (SNP) | VAF 60/120 reads (50%) | catalogued as COSV99917841; called by muse, mutect2, varscan2
- ZNF619 | c.1464G>A p.L488= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV100123255; called by muse, mutect2, varscan2
